Surgical pathology report (de-identified scan), TCGA case TCGA-PR-A5PG, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Roswell Park, specimen TCGA-PR-A5PG-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN(S): A. LEFT KIDNEY AND ADRENAL TUMOR
B. SPLENIC LESION
C. PERIAORTIC LYMPH NODES

ICD-O-3
Pheochromocytoma
Malignant 8706/3

CLINICAL HISTORY:

Site:
Path: Medulla of adrenal gland C94.1
CICF: Adrenal Gland NOS C74.9
JW 2/1/13

PRE-OPERATIVE DIAGNOSIS:

Left adrenal mass/Left ovarian/pelvic mass

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA: Left radical nephrectomy and adrenal tissue: Tumor mass between adrenal and kidney.

FSB: Splenic lesion: Benign vascular lesion, see comment.

Comment: Slides reviewed in daily pathology conference.

GROSS DESCRIPTION:

A. LEFT KIDNEY AND ADRENAL TUMOR

Received fresh labeled with patient name designated "A. left radical nephrectomy" is a 651 gm kidney with attached peri-renal fat, measuring overall 19x13x7cm. The specimen is inked black over the surface of the peri-renal fat. The specimen is bivalved to show a well circumscribed golden brown mass superior to the kidney measuring 9.0x8.0x3.0cm. The mass is directly adjacent to and pushing against the capsule of the kidney, but grossly does not penetrate the capsule. The center of the mass demonstrates firm fibrous parenchyma overlying the lesion there is a golden orange adrenal gland measuring 4.0x1.5x1.0cm. The kidney measures 11x6.5x5.0cm. The renal parenchyma is tan-brown with a well defined cortical medullary junction and orderly cortical striations and medullary rays. The pelvis and calyces appear smooth and gray-white. The peri-renal fat is inspected for lymph nodes. Gross photographs are taken. A portion of the specimen has been submitted for tissue procurement. Representative sections are submitted as follows:

- A1: ureter and blood vessel margin
- A2-A6: sections of mass at closest distance to peri-renal fat
- A7-A10: sections of lesion and capsule
- A11-A13: sections of lesion and adjacent overlying adrenal
- A14: section of unremarkable overlying adrenal and capsule
- A15-A16: additional sections of mass and capsule
- A17-A18: sections of mass with capsule and adjacent kidney parenchyma
- A19: section of renal pelvis
- A20: section of uninvolved kidney parenchyma

B. SPLENIC LESION

Received fresh labeled with the patient name designated "B. splenic lesion" is a fragment of red-brown soft tissue measuring 0.6x0.4x0.2cm. The entire specimen is submitted for frozen section in cassette FSB.

C. PERIAORTIC LYMPH NODES

[page 2 of 2]
Received in formalin in a container labeled with the patient name designated "C. periaortic lymph nodes" is a portion of beige-tan fibroadipose tissue measuring 6.5x3.0x1.2cm. Multiple possible firm beige-tan lymph nodes are identified, the largest measuring 2.0x2.0x1.0cm, the smallest 0.5x0.5x0.4cm. Cassettes are submitted as follows:

- C1-C2: 1 bisected lymph node
- C3-C4: 1 bisected lymph node
- C5: 3 possible lymph nodes
- C6: 4 possible lymph nodes
- C7-C8: additional possible lymph nodes

DIAGNOSIS:

A. ADRENAL GLAND AND KIDNEY, LEFT, RESECTION:

- MALIGNANT PHEOCHROMOCYTOMA, INVOLVING ADRENAL MEDULLA, AND EXTENDING TO PERI-ADRENAL ADIPOSE TISSUE, MEASURING 9 x 8 x 3 CM, SEE NOTE 1
- LYMPHOVASCULAR INVASION IDENTIFIED
- SURGICAL RESECTION MARGINS, NEGATIVE FOR PHEOCHROMOCYTOMA
- KIDNEY, NEGATIVE FOR TUMOR.

B. SPLEEN, BIOPSY:

- SPLENIC MESOTHELIAL CYST, SEE NOTE 2.

C. LYMPH NODES, PERI-AORTIC, RESECTION:

- METASTATIC PHEOCHROMOCYTOMA TO ONE OF TWELVE LYMPH NODES (1/12).

NOTE 1: The adrenal medulla is involved by proliferative neuroendocrine neoplasm. The tumor shows variable histologic architecture including zellballen, trabecular, and diffuse. The tumor cells show considerable pleomorphism with large bizarre nuclei and prominent nucleoli. The cytoplasm is amphophilic. While occasional mitoses and apoptotic bodies are seen, no necrosis is identified. The tumor involves the peri-adrenal adipose tissue and invades into small lymphatics and major blood vessel. The tumor is positive for Chromogranin A, Synaptophysin, S100 and negative for EMA. Ki67 marks about 3% of neoplastic cells. This immunoprofile is compatible with pheochromocytoma. Given the presence of the tumor in one lymph node, this tumor is considered malignant.

NOTE 2- The lesion is composed of multilocular microcystic structure lined with simple cuboidal cells. The cells are positive for AE1/3 and focally positive for Calretinin, and negative for CK5/6, CD31, and CD34. This immunoprofile is compatible with mesothelial cyst.

Reference:

Arber DA. Splenic mesothelial cysts mimicking lymphangiomas. Am J Surg Pathol 21(3), March 1997.

Criteria	W 1/30/13	No

Source: NCI Genomic Data Commons file b0e20494-4f61-4f0b-9a71-6bf651d03204 (TCGA-PR-A5PG.068C135F-563F-480E-A72E-F6D35A3F43FB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).